Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3B5, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3B5-01A (Primary Tumor).

[page 1 of 3]
Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- Right pelvic lymph nodes; dissection:
- Metastatic urothelial carcinoma with squamous differentiation in one of six lymph nodes (1/6).
- The tumor focus measure 0.4 cm.
- No extranodal extension present.
- Right distal ureter; excision:
- Segment of ureter, no tumor present.
- Left pelvic lymph nodes; dissection:
- Five lymph nodes, no tumor present (0/5).
- Bladder, prostate, seminal vesicles, vas deferens; cystoprostatectomy:
- Urothelial carcinoma of the urinary bladder, high grade, with extensive squamous differentiation and keratin production, invasive into the outer half of the muscularis propria.
- Multifocal urothelial carcinoma in situ (flat urothelial carcinoma) of the urinary bladder, involving surface urothelium and cystitis cystica.
- Margins of resection (soft tissue, prostatic urethra, right and left ureter), no tumor present.
- See pathologic parameters and comment.
- Prostate with high grade prostatic intraepithelial neoplasia (PIN).
- Seminal vesicles and vasa deferentia, no tumor present.
- Left distal ureter; excision:
- Segment of ureter, no tumor present.
- Right distal ureter; excision:
- Segment of ureter, no tumor present.

Urothelial Carcinoma Pathologic Parameters

- Tumor type: Urothelial carcinoma with extensive squamous differentiation
- Grade of tumor: High grade
- Depth of invasion: Muscularis propria, outer half
- Tumor distribution: Multifocal urothelial carcinoma in situ (trigone, posterior and anterior wall)
Invasive solitary urothelial carcinoma in the right posterior and lateral wall, measures 6.0 cm
- Ureteral margins: Negative
- Distal urethral margin: Negative
- Soft tissue margin or serosa: Negative
- Lymph nodes: Metastatic urothelial carcinoma with squamous differentiation in one of eleven lymph nodes (1/11)
- pTNM: pT2bN1MX

1C3-0-3
carcinoma, urothelial, ves 8.20/3
Site: bladder, wall, ves 6.7.9
CQCF: bladder, wall, posterior 6.7.4
10/21/11

Effective this Checklist utilizes the 7th edition TNM staging system for bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

[page 2 of 3]
Comment

The sections show multifocal urothelial carcinoma in situ (slides labeled D22, D25, D26 and D30). Although the entire portion of invasive carcinoma shows extensive squamous differentiation with keratin production, the presence of urothelial carcinoma in situ, by consent, defines this tumor as urothelial carcinoma with squamous differentiation.

xxx

[], M.D

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.

Electronically Signed Out by [], M.D

Clinical History:

The patient is an year-old male with a malignant neoplasm of bladder undergoing a cystectomy.

Specimens Received:

A: Right pelvic lymph nodes

B: Right distal ureter

C: Left pelvic lymph node

D: Bladder, prostate, seminal vesicles, vas deferens

E: Left distal ureter

F: Right distal ureter

Gross Description:

The specimens are received in six containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of rubbery yellow-tan tissue measuring 6.0 x 3.2 x 1.3 cm, which is dissected for lymph node candidates. Six rubbery tan-yellow lymph node candidates are identified ranging in size from 0.3-4.8 cm. Representative sections are submitted as follows:

A1: 3 lymph node candidates

A2: One lymph node candidate

A3: One lymph node candidate, trisected

A4-A6: One lymph node candidate, serially sectioned

B. The second container is additionally identified as, "right distal ureter". Received fresh and placed in formalin is an unoriented 0.9 cm in length by 0.4 cm in diameter tubular segment of tan-pink tissue which is bisected and submitted entirely as B1 (opposite ends placed en face in cassette).

C. The third container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin is an aggregate of rubbery yellow-tan tissue measuring 4.0 x 3.2 x 1.5 cm, which is dissected for lymph node candidates. Five rubbery tan-yellow lymph node candidates are identified ranging in size from 0.3-2.7 cm. Representative sections are submitted as follows:

C1: One lymph node candidate

C2: One lymph node candidate, bisected

C3: One lymph node candidate

C4: One lymph node candidate, bisected

C5: One lymph node candidate, bisected

D. The fourth container is additionally identified as, "bladder, prostate,

[page 3 of 3]
seminal vesicles, vas deferens". Received fresh and placed in formalin is a 310.5 g, 16.0 x 10 x 4.5 cm cystoprostatectomy specimen consisting of a 7.0 x 6.5 x 4.0 cm bladder with attached mesenteric fat and a 5.0 x 3.9 x 3.2 cm prostate. The right seminal vesicles measures 5.0 x 2.0 x 0.9 cm and right vas deferens measures 12.5 cm in length by 0.2-0.4 cm in diameter. The left seminal vesicles measures 4.5 x 2.0 x 0.7 cm and left vas deferens measures 6.5 cm in length by 0.5 cm in diameter. The right ureteral stump measures 1.1 cm in length by 0.4 cm in diameter, the left measures 2.0 cm in length and 0.4 cm in diameter. The right ureter is not probe patent and the left ureter is probe patent.

The right half of the prostate is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact shaggy membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity which disrupts the prostatic urethra mucosa. The right aspect of the prostate exhibits solid tan-yellow areas intermixed with cystic spaces throughout the entire half from apex to base. The solid components range in size from 0.6-1.5 cm, and the closest is 0.3 cm from the inked outer surface. The left half of the prostate exhibits spongy tan tissue, from apex to base, intermixed with small tan-brown calculi. The anterior aspect of the prostate, from apex to base, demonstrates ill-defined areas of smooth glistening tan-white to purple rubbery tissue which focally abuts the inked outer surface.

The opened bladder reveals a 6.0 x 6.0 x 3.0 cm exophytic, friable tan-red to brown mass in the right posterior and right lateral wall. On cut section, the mass has a pale tan cut surface, intermixed with scattered areas of hemorrhage, which extends through the bladder wall and comes to within 0.2 cm of the black inked surface. The surrounding bladder mucosa is wrinkled tan-pink to purple with wall thicknesses ranging from 0.7-1.4 cm. The right ureteral orifice is not identified at the trigone and is not probe patent. The left ureteral orifice is identified and probes patent.

Gross photographs are taken. Representative sections are submitted as follows:

- D1: Left ureter margin
- D2: Right ureter margin
- D3: Prostatic urethral margin
- D4: Prostatic apical margin, shaved and perpendicularly sectioned
- D5: Next cross section after prostatic apical margin
- D6-D10: Representative sections of right half of prostate submitted sequentially from apex to base
- D11-D17: Representative sections of left half of prostate submitted sequentially from apex to base
- D18: Representative sections of left seminal vesicle and vas deferens
- D19: Representative sections of right seminal vesicle and vas deferens
- D20-D25: Representative sections of mass (deepest extent in cassette D20)
- D26: Uninvolved trigone
- D27: Uninvolved posterior bladder wall
- D28: Uninvolved left bladder wall
- D29: Uninvolved bladder dome
- D30: Uninvolved anterior bladder wall

E. The fifth container is additionally identified as, "left distal ureter". Received fresh and placed in formalin is a 2.1 cm in length by 0.4 cm in diameter tubular segment of tan-pink tissue which is surrounded by shaggy tan-yellow to pink tissue. A suture designates the non-marginal side and the specimen probes patent. The margin side is amputated and submitted en face as E1.

F. The sixth container is additionally identified as, "right distal ureter". Received fresh and placed in formalin is a 2.1 cm in length by 0.5 cm in diameter tubular segment tan-pink tissue with a small amount of attached tan-yellow tissue. A suture designates the non-marginal side and probes patent.

Source: NCI Genomic Data Commons file 36277c0a-b7e0-4f5d-8b3a-bff3a6916abd (TCGA-FD-A3B5.683132FE-FCA5-4D03-A018-45D36B12FFD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).